Surgical pathology report (de-identified scan), TCGA case TCGA-AF-6655, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-AF-6655-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

Date Coll: [REDACTED]

SURGICAL PATHOLOGY REPORT

SPECIMEN

- A. Apical lymph node
- B. Rectum and sigmoid

CLINICAL NOTES

--

GROSS DESCRIPTION

- A. Received unfixed, labeled left apical lymph node, is a 0.7 x 0.5 x 0.4 cm lymph node, entirely submitted in one block. AS-1.
- B. Received fresh subsequently fixed in formalin labeled "rectosigmoid" is a 24 cm. long portion of colon. The proximal end is stapled and is inked blue, the distal end is opened and is inked black. The specimen is partially covered with pink tan smooth glistening serosa showing a 1.2 cm area of submucosal hemorrhage, 2.8 cm. from the proximal end. The retroperitoneal reflection is 6.5 cm. from the distal margin. The specimen is opened to show a pink tan smooth glistening mucosa which has an average circumference of 5.5 cm. at the proximal end and 9.5 cm. at the distal end. There is a submucosal darkly discolored maroon area, 2.5 x 1.2 cm., located 3 cm. from the proximal end. No discrete gross lesions are identified. At the distal end is a 2.5 x 2.5 x 0.5 cm. tumor which is exophytic having a flat surface. This comes within 3 cm. of the distal margin. The cut surface of this shows invasion into the muscularis propria, coming within 1.5 cm. of radial margin. No other discrete gross lesions are identified. A portion of tumor is submitted for tissue procurement, as requested. Possible lymph node are grossly identified in the surrounding fat. Representative sections of the specimen are submitted as follows: block 1 - representative luminal margins; block 2 and 3 - representative sections of submucosal hemorrhage which was previously considered to be inking; block 4-5 - representative section of tumor to deep margin; block 6 - representative section of tumor to normal; block 7 - has six possible lymph nodes; block 8 - has five possible lymph nodes; block 9 - has six possible lymph nodes; block 10 and 11 - six e lymph nodes each; block 12 - has two lymph nodes. RS12.
- [REDACTED]
- [REDACTED]

MICROSCOPIC DESCRIPTION

Histologic type: Adenocarcinoma
Histologic grade: Moderately-differentiated
Primary tumor (pT2): Carcinoma into, but not through, muscularis propria.
Proximal/distal/radial margins: Negative.
Vascular invasion: Not identified.
Regional lymph nodes (pN): Metastatic carcinoma in 2 of 29 lymph nodes (2/29)
Non-lymph node pericolic tumor: Not identified.
Other findings: Diverticuli.

[page 2 of 2]
[REDACTED]

DIAGNOSIS

- A. Apical lymph node, biopsy:
- One negative lymph node (0/1).
- B. Sigmoid colon and rectum, segmental resection:
- Adenocarcinoma (rectum), moderately-differentiated, with invasion into, but not through, the muscularis propria (pT2).
- Negative margins of excision.
- Metastatic carcinoma in two of twenty-eight lymph nodes (2/28).
- [REDACTED]

--- End Of Report ---

Source: NCI Genomic Data Commons file bd45a51c-875f-499e-b60a-d7731ec216fe (TCGA-AF-6655.7DDD7E74-CB49-401A-9B69-668909BDB9DF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).